Somatic mutation profile of tumor specimen C3N-00517-01 (aliquot CPT0093860009_1) from CPTAC case C3N-00517, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 69.6 years (25,407 days).
Specimen C3N-00517-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6d7129cd-3013-47ba-9b3b-1c619cfe7d47.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00517-31 (Blood Derived Normal), aliquot CPT0093920002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/af901528-4f03-43d9-89cf-d615578c1739

The open-access MAF lists 9 somatic variants for this specimen: 4 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Silent 3, 3'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AMPD1 | c.974G>A p.R325Q | Missense Mutation (SNP) | VAF 19/674 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1290122973; called by muse, mutect2
- HMCN1 | c.10699C>T p.R3567W | Missense Mutation (SNP) | VAF 18/500 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1382158216; called by muse, mutect2
- HMCN2 | c.322G>A p.V108M | Missense Mutation (SNP) | VAF 13/394 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs1001455138, COSV70279763; called by muse, mutect2
- TTN | c.8621A>T p.K2874I (on ENST00000591111; = p.K2828I on NM_003319.4) | Missense Mutation (SNP) | VAF 24/864 reads (3%) | PolyPhen possibly damaging (0.878); called by muse, mutect2
- KCNA4 | c.1230C>A p.V410= | Silent (SNP) | VAF 12/306 reads (4%) | catalogued as COSV100069354; called by muse, mutect2
- LRP8 | c.582C>T p.D194= | Silent (SNP) | VAF 26/844 reads (3%) | called by muse, mutect2
- ZNF699 | c.1116C>T p.F372= | Silent (SNP) | VAF 16/434 reads (4%) | catalogued as COSV58026403; called by muse, mutect2
- CACNA1S | c.*31C>T | 3'UTR (SNP) | VAF 20/528 reads (4%) | called by muse, mutect2
- PLEKHM1P1 | n.1419C>G | RNA (SNP) | VAF 42/1208 reads (3%) | called by muse, mutect2
